Gene-level copy-number profile of tumor specimen TCGA-VQ-A91U-01A from TCGA case TCGA-VQ-A91U, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 78.8 years (28,791 days).
Specimen TCGA-VQ-A91U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.70deb1bc-7043-47cf-88a0-3361c5c9f2fc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VQ-A91U-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8d59b744-74b2-40de-a98d-e8541e3e5e97

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 4; copy number 2: 16,317; copy number 3: 17,845; copy number 4: 17,560; copy number 5: 4,699; copy number 6: 787; copy number 7: 828; copy number 8: 1,472; copy number 9: 50; copy number 11: 136; copy number 12: 11; copy number 13: 45; copy number 14: 9; copy number 16: 16; copy number 49: 33; copy number 68: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VQ-A91U-01A-11D-A40Z-01): tumor purity 0.56, ploidy 3.53, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:41,711,520–41,767,089, 5 genes: LINC00479, LINC00112, RIPK4, AP001615.1, MIR6814.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,603 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:41,494,853–58,438,364, 330 genes, copy number 7–16 (broad region; genes not listed).
- chr6:67,210,408–69,867,236, 20 genes, copy number 7: AL591004.1, AL365503.1, RNA5SP208, RNU6-280P, Y_RNA, AL713998.1, AL713998.3, AL713998.4, AL713998.2, AL646090.2, AL646090.1, AL593844.1, LINC02549, AL606923.2, AL606923.1, AL391807.1, ADGRB3, LMBRD1, NPM1P37, GAPDHP42.
- chr8:42,416,475–145,066,685, 1,577 genes, copy number 7–9 (within-gene range 2–9) (broad region; genes not listed).
- chr11:77,813,319–79,612,300, 36 genes, copy number 49–68: AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2, AP003110.1, RNU6-311P, COPS8P3, TENM4, AP002768.1, AP002957.1, AP001547.1, MIR708, MIR5579, AP001978.1.
- chr11:98,565,074–103,092,194, 57 genes, copy number 8–13: AP003038.1, AP003715.1, AP002428.1, CNTN5, RN7SKP53, RPA2P3, RN7SL222P, PPIAP43, ARHGAP42-AS1, ARHGAP42, RN7SKP115, PGR, PGR-AS1, AP001533.1, TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3, AP001486.1, DCUN1D5, AP001486.2.
- chr13:18,467,172–38,622,671, 406 genes, copy number 8 (broad region; genes not listed).
- chr13:83,298,071–84,902,424, 13 genes, copy number 8: RNU6-67P, AL353688.1, SLITRK1, AL355481.1, VENTXP2, AL590681.1, UBE2D3P4, AL445604.1, AL162493.1, MTND4P1, MTND5P3, LINC00333, AL445588.1.
- chr13:103,444,620–114,337,626, 164 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
